Gene-level copy-number profile of tumor specimen TARGET-40-PANGRW-01A from TARGET case TARGET-40-PANGRW, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.7 years (6,088 days).
Specimen TARGET-40-PANGRW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.e8f4c3fd-d731-5996-9ccc-34edf2fdb26c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PANGRW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 377 have no estimate.
https://portal.gdc.cancer.gov/files/d2f16c6d-8296-4a1e-9566-166e04ce4ba8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1,073; copy number 1: 2,195; copy number 2: 10,190; copy number 3: 26,579; copy number 4: 13,129; copy number 5: 4,851; copy number 6: 926; copy number 7: 748; copy number 8: 373; copy number 9: 181; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:165,349,030–165,905,608, 4 genes: AC008415.1, RN7SKP60, AC008562.1, AC008489.1.
- chr11:55,635,113–55,652,854, 2 genes: OR4P4, OR4S2.
- chr11:84,545,131–84,640,565, 2 genes: HNRNPA1P72, AP000852.1.
- chr13:75,549,773–75,807,120, 1 gene (within-gene range 0–2): AL137782.1.
- chr13:75,620,434–75,859,870, 1 gene (within-gene range 0–2): LMO7.
- chr13:75,688,556–75,689,197, 1 gene: FAM204CP.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,302 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:23,929,070–27,395,814, 139 genes, copy number 9 (broad region; genes not listed).
- chr1:53,506,237–111,989,668, 949 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr2:88,811,186–88,861,563, 2 genes, copy number 7 (within-gene range 4–7): MALLP2, AC244205.1.
- chr2:88,857,161–94,787,261, 125 genes, copy number 7 (broad region; genes not listed).
- chr7:22,118,236–22,357,154, 2 genes, copy number 7 (within-gene range 5–7): RAPGEF5, RNA5SP227.
- chr7:22,510,616–22,511,999, 1 gene, copy number 8: EEF1A1P6.
- chr12:3,124,777–3,125,063, 1 gene, copy number 7: Metazoa_SRP.
- chr14:18,333,726–19,957,996, 83 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 876. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
